Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0F, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0F-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/3/14

Date of procurement:

Pathohistological diagnosis

Seminoma, right testicle

Description:

A testicle with tumor, size 5.5x3.5x3 cm with 10 cm long funiculus was received. At the surface of the testicle we see 2.5 cm long surgical cut with sutures. At the cut we see gray-white, partially necrotic and bloody tumor 3.9x3x2.5 cm in size.

Histologically, the tumor is made of solid clusters of round and oval bright cells with dark nuclei and partially emphasized nucleolus. Around tumor cell seats we see connecting tissue containing abundant lymphocyte infiltrations. On numerous locations we see that the tumor tissue is affected by necrosis and hemorrhaging.

Tumor tissue is not present in rete testis.

Tumor is not present in funiculus.

Dual/Synchopous Primary Noted		✓

Source: NCI Genomic Data Commons file 07eedf6c-587a-49f7-a02f-562b3a169a4a (TCGA-ZM-AA0F.84D4CE57-7725-4595-8725-0F3F0BF3A855.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).